Surgical pathology report (de-identified scan), TCGA case TCGA-24-1565, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1565-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

FINAL

24-1565

*** Converted Case * This report may not match the original report format**

DIAGNOSIS:

FS, OVARY, LEFT, OOPHORECTOMY
-- SEROUS CARCINOMA, POORLY DIFFERENTIATED (SEE COMMENT)

FALLOPIAN TUBE, LEFT, SALPINGECTOMY
-- NO EVIDENCE OF MALIGNANCY

OVARY, RIGHT, OOPHORECTOMY
-- SEROUS CARCINOMA

FALLOPIAN TUBE, RIGHT, SALPINGECTOMY
-- SEROUS CARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
-- SQUAMOUS METAPLASIA

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
-- ENDOMETRIAL POLYP
-- ATROPHIC

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
-- METASTATIC SEROUS CARCINOMA

OMENTUM, OMENTECTOMY - METASTATIC SEROUS CARCINOMA

LYMPH NODE, LEFT PELVIC, DISSECTION
-- METASTATIC SEROUS CARCINOMA IN THREE OF FOUR LYMPH NODES (3/4)

LYMPH NODE, LEFT INGUINAL, DISSECTION
-- METASTATIC SEROUS CARCINOMA IN 7 OF 7 LYMPH NODES (7/7)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

Intraoperative Consultation:

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

FS, ovary, left, excision - "Poorly differentiated adenocarcinoma,
favor Mullerian primary," [REDACTED]

Microscopic Description and Comment:

Sections from the right and left ovary show a poorly differentiated serous carcinoma that is mainly solid with foci of papillary growth. The tumor shows moderate nuclear pleomorphism, scattered prominent nucleoli, and occasional mitoses. Extensive lymphovascular invasion is identified, especially in sections from the right ovary. The tumor involves the left ovary, the right fallopian tube and the serosal surface of the uterus. The omentum shows extensive involvement with tumor. Three out of four left pelvic lymph nodes and seven of seven left inguinal lymph nodes show metastatic carcinoma. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G2 (Moderately-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. The presence of tumor invasion of the mesovarium CANNOT BE EVALUATED.
8. Tumor DOES invade the adjacent fallopian tube.
9. Tumor invasion of the pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 30.0 cm (Enter "0" if no implants.)
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are PRESENT.
17. The total number of regional lymph nodes examined is 11
18. The total number of metastatically-involved regional lymph nodes is 10
Extranodal extension by tumor metastases is ABSENT
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIc	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver.

THE REGIONAL LYMPH NODES are classified as:

N1 (Nodes contain metastatic tumor)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

History:

The patient is a [REDACTED] with a left ovarian mass.
Operative procedure: Oophorectomy.

An intraoperative non-microscopic consultation was obtained and interpreted as: "Ovary, left - Received is an ovary measuring 9.5 x 8.0 x 4.5 cm. with a papillary tumor present on the serosal

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

surface. It is sectioned to reveal a white-tan, firm, solid and papillary tumor. A portion frozen for tumor repository," [REDACTED]

Specimen(s) Received:

A: FS1-OVARY, LEFT
B: LEFT OVARY
C: OMENTUM
D: LEFT PELVIC LYMPH NODE
E: UTERUS
F: LEFT INGUINAL LYMPH NODE

Gross Description:

The specimens are received in six containers of formalin, each labelled with the patient's name. The first is labelled "FS" and contains a single fragment of white-tan tissue measuring 2.2 x 1.1 x 0.1 cm. [REDACTED]

The second container is labelled "left ovary" and contains a previously inked and sectioned ovary measuring 9.5 x 8.0 x 4.5 cm. An unremarkable segment of fallopian tube measuring 8.5 x 0.5 cm. is adhered to the surface. The surface of the ovary itself is multinodular. Several nodules present on the surface are grossly suspicious for tumor. Cut sections of the tumor show a predominantly solid, white-tan tumor with a nodular configuration and white, fibrous bands extending between in the nodules. A complex serous, fluid-filled mass is also present at the surface. Focal areas show possible mucin production. Labelled LT, left fallopian tube; X1, complex cystic area; X2, papillary excrescences at surface; X3-X6, main tumor mass. [REDACTED]

The third container is labeled "uterus" and contains a uterus with attached right adnexal structures weighing 44 grams. The uterus measures 5.5 cm superior-to-inferior x 4.0 cm cornu-to-cornu x 2.1 cm anterior-to-posterior. The cervix measures 2.0 x 1.8 x 2.0 cm, with a 1.0 cm os. The ectocervix shows punctate hemorrhage but is otherwise grossly unremarkable. The endocervix is grossly unremarkable. The endometrium shows a polyp filling approximately 75% of the endometrial cavity. The polyp is exophytic, attached to the left cornu, and measures 1.2 x 0.9 x 0.3 cm. There is no gross evidence of invasion. The myometrium shows several subserosal leiomyomas, the largest measuring 1.0 cm in diameter, each is well-circumscribed, white-tan, and whorled without hemorrhage or necrosis. The anterior serosal surface also shows several soft tissue nodules, the largest measuring 0.7 cm in diameter. These are firm and yellow-white, and are grossly suspicious for metastatic tumor. The right fallopian tube measures 9.0 cm in length and 0.5 cm in diameter at the mid portion. The distal end shows no obvious fimbria, but there are numerous tubo-ovarian adhesions. Cystic and solid Walthard rests are present. The distal portion of the fallopian tube is filled with serous fluid. It is dilated to a diameter of 1.4 cm. The right ovary measures 2.5 x 1.1 x 0.8 cm. The serosal surface is tan-white and nodular. Sections show unremarkable yellow-white ovarian tissue. Two tan-white firm nodules are present in the paraovarian soft tissue, measuring 0.5 and 0.3 cm in diameter. Labeled CX1 - anterior cervix; CX2 - posterior cervix; EM1 - anterior endomyometrium; EM2 - posterior endomyometrium with polyp; M - subserosal leiomyomas; S - anterior serosal nodule; - right ovary with paraovarian soft tissue nodule; RT - right fallopian tube. [REDACTED]

The fourth container is labeled "omentum" and contains a sheet of fibroadipose tissue measuring 30 x 11 x 3.0 cm. The omentum is diffusely replaced by infiltrating white tumor and approximately 80% of the omental volume. [REDACTED]

The fifth container is labeled "left pelvic lymph node." It contains two fragments of fibroadipose tissue measuring 6.0 x 4.0 x 1.0 cm in aggregate. Several lymph nodes measuring 1.0 to 1.8 cm in maximum diameter are identified. These are all grossly suspicious for involvement by tumor. [REDACTED]

The sixth container is labeled "left inguinal lymph node." It contains fragments of fibroadipose tissue with embedded lymph node, measuring 6.5 x 4.5 x 1.5 cm in aggregate. Several lymph nodes measuring 0.7 to 1.5 cm in maximum dimension are identified; all are grossly involved by malignancy. [REDACTED]

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 51cc96f3-70e9-4a19-9898-a0eff87d1f9c (TCGA-24-1565.F424905E-3DC2-4E37-B6C4-8A77C7CE817B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).